Somatic mutation profile of tumor specimen C3L-01836-01 (aliquot CPT0086860009) from CPTAC case C3L-01836, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 47.1 years (17,215 days).
Specimen C3L-01836-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a78f68e-8504-427d-9cc1-6fcc36b489ad.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01836-31 (Blood Derived Normal), aliquot CPT0087440002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e77971a-d49b-4fbd-ba2f-e25a5ef0ac64

The open-access MAF lists 23 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 6, 5'UTR 3, Intron 2, In Frame Del 1, Frame Shift Ins 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- INHBE | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0.069); catalogued as rs372615182; called by muse, mutect2, varscan2
- SUN5 | c.874G>A p.A292T | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs376507648; called by muse, mutect2, varscan2
- AGTRAP | c.143G>C p.R48P | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ATIC | c.1297G>A p.V433M | Missense Mutation (SNP) | VAF 62/395 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- KLHL30 | c.896_898del p.N299del | In Frame Del (DEL) | VAF 6/43 reads (14%) | called by pindel, varscan2
- LYST | c.10406G>T p.W3469L | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- NEURL1B | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH17 | c.2169G>A p.M723I | Missense Mutation (SNP) | VAF 59/379 reads (16%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PRRC2A | c.6176_6179del p.Q2059Lfs*5 | Frame Shift Del (DEL) | VAF 14/66 reads (21%) | called by mutect2, pindel, varscan2
- SYNE2 | c.17918T>G p.L5973* | Nonsense Mutation (SNP) | VAF 36/322 reads (11%) | called by muse, mutect2
- VHL | c.168_169dup p.G57Afs*11 | Frame Shift Ins (INS) | VAF 29/222 reads (13%) | called by mutect2, pindel, varscan2
- ZNF324 | c.234C>A p.N78K | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DCAF8L1 | c.141G>A p.S47= | Silent (SNP) | VAF 48/128 reads (38%) | catalogued as rs760112871, COSV101491428, COSV101491459; called by muse, mutect2, varscan2
- IGFN1 | c.3498C>T p.H1166= (on ENST00000295591 / NM_001367841.1; = p.H3623= on NM_001164586.2) | Silent (SNP) | VAF 33/174 reads (19%) | called by muse, mutect2, varscan2
- PHLDB3 | c.1503C>T p.P501= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as rs1210066990; called by muse, mutect2
- SPAG1 | c.1774C>T p.L592= | Silent (SNP) | VAF 24/244 reads (10%) | called by muse, mutect2
- ZNF227 | c.585T>A p.I195= | Silent (SNP) | VAF 15/140 reads (11%) | called by muse, mutect2, varscan2
- ZNF721 | c.762A>G p.K254= (on ENST00000338977; = p.K266= on NM_133474.4) | Silent (SNP) | VAF 31/165 reads (19%) | catalogued as rs781912933; called by muse, mutect2, varscan2
- CUBN | c.-37G>A | 5'UTR (SNP) | VAF 41/232 reads (18%) | called by muse, mutect2, varscan2
- FSTL1 | c.331+106C>A | Intron (SNP) | VAF 58/309 reads (19%) | called by muse, mutect2, varscan2
- MYOM3 | c.1970+40T>C | Intron (SNP) | VAF 8/211 reads (4%) | called by muse, mutect2
- ZNF417 | c.-25G>A | 5'UTR (SNP) | VAF 37/205 reads (18%) | catalogued as rs773481811; called by muse, mutect2, varscan2
- ZNF846 | c.-29C>T | 5'UTR (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
